Gene-level copy-number profile of tumor specimen REBC-ACFI-TTM1-A from REBC case REBC-ACFI, project REBC-THYR (Comprehensive genomic characterization of radiation-related papillary thyroid cancer in the Ukraine). Sex at birth: male; Primary diagnosis: Papillary adenocarcinoma, NOS; Tissue or organ of origin: Thyroid gland.
Specimen REBC-ACFI-TTM1-A: Sample type: Metastatic; Tissue type: Tumor; Tumor descriptor: Metastatic; Specimen type: Solid Tissue; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a7f0875b-15ab-4aed-b621-a406815e88e8.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator REBC-ACFI-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 1,717 have no estimate.
https://portal.gdc.cancer.gov/files/65ff3960-4af5-47cc-a2ad-f91ef8fda9eb

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 10; copy number 1: 3,243; copy number 2: 55,472; copy number 3: 181.

Homozygous deletions (total copy number 0; autosomes only): 10 genes in 1 contiguous region (coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr22:21,167,758–21,325,042, 10 genes (within-gene range 0–2): FAM230B, AP000550.2, FAM247A, GGT2, AP000550.3, E2F6P3, POM121L8P, BCRP6, FAM230H, AP000552.2.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): none.

Autosomal genes at a single copy (total copy number 1): 387. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
